Somatic mutation profile of tumor specimen ALCH-B3GD-TTP1-A (aliquot ALCH-B3GD-TTP1-A-5-0-D-A78R-36) from ALCHEMIST case ALCH-B3GD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.7 years (26,542 days).
Specimen ALCH-B3GD-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25c2c871-0e68-40a7-95c7-f2dadd741cd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3GD-NB1-A (Blood Derived Normal), aliquot ALCH-B3GD-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5df8ffa4-7ac2-45a4-9cff-fd79b9b7c269

The open-access MAF lists 36 somatic variants for this specimen: 30 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 5, Splice Site 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 84/704 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ATXN3L | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV66075897; called by muse, mutect2, varscan2
- CUL2 | c.1076A>G p.N359S | Missense Mutation (SNP) | VAF 11/304 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.065); catalogued as COSV101039295; called by muse, mutect2
- GAD2 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 16/393 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276993275, COSV52163477; called by muse, mutect2
- MED12L | c.5678G>A p.R1893Q | Missense Mutation (SNP) | VAF 42/741 reads (6%) | SIFT tolerated, low confidence (0.72); PolyPhen probably damaging (0.968); catalogued as rs761647557, COSV56378870; called by muse, mutect2
- PTPRS | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 16/299 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1369452734; called by muse, mutect2
- RANGRF | c.276C>A p.N92K | Missense Mutation (SNP) | VAF 8/244 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0.133); catalogued as rs1215638683; called by muse, mutect2
- SHMT1 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs375373531; called by muse, mutect2, varscan2
- TGFBR1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 22/742 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1057519144, COSV100895231; ClinVar: uncertain significance; called by muse, mutect2
- UTP20 | c.6051G>A p.M2017I | Missense Mutation (SNP) | VAF 12/277 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV55381158; called by muse, mutect2
- AP3D1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EP300 | c.6959C>T p.S2320F | Missense Mutation (SNP) | VAF 12/255 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); called by muse, mutect2
- GPRASP1 | c.3770G>T p.G1257V | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KNSTRN | c.866T>G p.F289C | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2
- KRTAP22-2 | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 11/295 reads (4%) | PolyPhen possibly damaging (0.887); called by muse, mutect2
- LRRC37A3 | c.3553C>A p.Q1185K | Missense Mutation (SNP) | VAF 53/1317 reads (4%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.678); called by muse, mutect2
- PIEZO1 | c.5862C>A p.Y1954* | Nonsense Mutation (SNP) | VAF 19/387 reads (5%) | called by muse, mutect2
- PLCG1 | c.2982G>C p.K994N | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- POLR2C | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 12/357 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2
- POLR2C | c.743C>G p.A248G | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- RBM10 | c.2450_2456del p.R817Lfs*28 | Frame Shift Del (DEL) | VAF 29/228 reads (13%) | called by mutect2, pindel
- RBM15 | c.2237A>C p.E746A | Missense Mutation (SNP) | VAF 16/526 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- RPRD1B | c.617A>T p.Q206L | Missense Mutation (SNP) | VAF 12/347 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- SEMA3A | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 75/542 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SERPINB3 | c.136A>G p.K46E | Missense Mutation (SNP) | VAF 24/383 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- SLC7A14 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPOPL | c.714+1G>T p.X238_splice | Splice Site (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
- TMEM69 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- TNXB | c.1996G>T p.V666L | Missense Mutation (SNP) | VAF 15/440 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2
- ZCCHC18 | c.481C>A p.Q161K | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- AKAP12 | c.5253G>A p.V1751= | Silent (SNP) | VAF 9/249 reads (4%) | catalogued as rs1326401385, COSV53578556; called by muse, mutect2
- GLI2 | c.3249C>T p.P1083= (on ENST00000361492 / NM_001374353.1; = p.P1100= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/468 reads (6%) | called by muse, mutect2
- L1CAM | c.459A>C p.S153= | Silent (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- OR2T4 | c.732G>T p.V244= | Silent (SNP) | VAF 36/936 reads (4%) | called by muse, mutect2
- USP9X | c.1956A>G p.Q652= | Silent (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- AC136628.2 | n.946G>A | RNA (SNP) | VAF 12/422 reads (3%) | catalogued as rs1471461951; called by muse, mutect2
